Somatic mutation profile of tumor specimen TCGA-HC-A9TE-01A (aliquot TCGA-HC-A9TE-01A-11D-A41K-08) from TCGA case TCGA-HC-A9TE, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.5 years (23,543 days).
Specimen TCGA-HC-A9TE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1c06dd7-24ba-4d73-8218-f96ef25163a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A9TE-10A (Blood Derived Normal), aliquot TCGA-HC-A9TE-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff4fc28f-840b-4b5a-aeb2-e647814023bd

The open-access MAF lists 57 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 3, Frame Shift Del 2, Intron 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.445del p.S149Pfs*21 | Frame Shift Del (DEL) | VAF 23/44 reads (52%) | catalogued as rs1064793929, COSV52688587, COSV52700895; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABHD11 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs374778806; called by muse, mutect2
- ANO10 | c.1769A>G p.D590G | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as COSV99428029; called by muse, mutect2
- AP3B2 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99916024; called by muse, mutect2
- ASCC2 | c.1069T>G p.L357V | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100315951; called by muse, mutect2, varscan2
- BRWD1 | c.3866G>T p.S1289I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as rs775100706, COSV100312712; called by muse, mutect2, varscan2
- C6 | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752796479, COSV54706183, COSV54714342; called by muse, mutect2, varscan2
- CAD | c.2737C>T p.Q913* | Nonsense Mutation (SNP) | VAF 32/73 reads (44%) | catalogued as COSV99254359; called by muse, mutect2, varscan2
- CCNB2 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759811496, COSV55595051; called by muse, mutect2, varscan2
- CHD3 | c.2522G>T p.G841V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100390635; called by muse, mutect2, varscan2
- CYFIP1 | c.530T>C p.M177T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs750888124; called by muse, mutect2, varscan2
- EFHB | c.802A>T p.I268F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99859062; called by muse, mutect2
- EML2 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV99839519; called by muse, mutect2
- ETF1 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100860020; called by muse, mutect2
- ETV2 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs1300677837, COSV99876791; called by muse, mutect2
- FBXO28 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100837338; called by muse, mutect2
- GALNS | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99242833; called by muse, mutect2, varscan2
- HPS3 | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV99937101; called by muse, mutect2, varscan2
- KCNJ16 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs747458721, COSV52252627; called by muse, mutect2, varscan2
- KCNK5 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1476911836, COSV100851718, COSV63988964; called by muse, mutect2, varscan2
- KRT31 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs776469040, COSV52433602, COSV52436665; called by muse, mutect2, varscan2
- LAMA1 | c.1846G>T p.G616* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as rs146460281, COSV101054855; called by muse, mutect2, varscan2
- LINGO2 | c.1734C>A p.D578E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100430100; called by muse, mutect2, varscan2
- MMP19 | c.1133C>G p.P378R | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV100490946; called by muse, mutect2, varscan2
- MOS | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100322708; called by muse, mutect2
- NDUFB10 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as COSV99238677; called by muse, mutect2, varscan2
- NME5 | c.560G>A p.W187* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs1264772681, COSV99496700; called by muse, mutect2, varscan2
- NOTCH3 | c.1191C>T p.I397= | Splice Region (SNP) | VAF 33/76 reads (43%) | catalogued as rs144214159; called by muse, mutect2, varscan2
- PCDHB4 | c.1493C>G p.P498R | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as rs1302319280, COSV99521822; called by muse, mutect2, varscan2
- PRAMEF6 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 32/491 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs1213937863; called by muse, mutect2
- PROS1 | c.1306A>T p.S436C | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV67776117; called by muse, mutect2, varscan2
- PRR19 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs972798619, COSV100003601; called by muse, mutect2, varscan2
- PTCHD1 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101037218; called by muse, mutect2, varscan2
- SEMA4C | c.1631C>G p.S544W | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV100560716, COSV59691828; called by muse, mutect2, varscan2
- SERPINB12 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs200518644, COSV54032923, COSV54035304; called by muse, mutect2, varscan2
- TRIM69 | c.1112G>A p.R371K (on ENST00000329464 / NM_182985.5; = p.R212K on NM_080745.5) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs202081848, COSV100274148; called by muse, mutect2, varscan2
- TTN | c.86656G>A p.E28886K (on ENST00000591111; = p.E21462K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | PolyPhen probably damaging (0.994); catalogued as COSV100592831; called by muse, mutect2
- UBE2S | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99198759; called by muse, mutect2, varscan2
- ZC3H13 | c.3982G>C p.D1328H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); catalogued as COSV99667383; called by muse, mutect2
- ZNFX1 | c.2225G>A p.G742D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100870718; called by muse, mutect2, varscan2
- EID3 | c.175del p.V59* | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
- TRAPPC8 | c.2582_2584del p.C861_H862delinsY | In Frame Del (DEL) | VAF 29/96 reads (30%) | called by mutect2, pindel, varscan2
- AGTR2 | c.870C>T p.C290= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV64156392; called by muse, mutect2, varscan2
- B3GNT3 | c.396C>T p.R132= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs781448394, COSV100592619; called by muse, mutect2, varscan2
- CD109 | c.363C>T p.R121= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV99752468; called by muse, mutect2, varscan2
- CRHBP | c.369C>T p.F123= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV99169439; called by muse, mutect2
- DOCK8 | c.2979C>T p.S993= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV101209783; called by muse, mutect2, varscan2
- MUC16 | c.24435G>A p.V8145= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV67450587; called by muse, mutect2, varscan2
- MXRA5 | c.6648C>T p.A2216= | Silent (SNP) | VAF 83/105 reads (79%) | catalogued as rs187308634, COSV99475593; called by muse, mutect2, varscan2
- NET1 | c.1143C>A p.I381= (on ENST00000355029 / NM_001047160.3; = p.I327= on NM_005863.5) | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV100742196, COSV100742284; called by muse, mutect2, varscan2
- NHS | c.975G>A p.P325= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV101196373; called by muse, mutect2
- PDE4B | c.126G>C p.G42= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV100302092; called by muse, mutect2
- PKP3 | c.453C>G p.A151= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs771747821, COSV100520674; called by muse, varscan2
- UGT2B10 | c.1443C>T p.N481= | Silent (SNP) | VAF 46/169 reads (27%) | catalogued as COSV99607824; called by muse, mutect2, varscan2
- UGT2B11 | c.63G>A p.G21= | Silent (SNP) | VAF 96/169 reads (57%) | catalogued as COSV101485213; called by muse, mutect2, varscan2
- MASP1 | c.1303+5161C>T | Intron (SNP) | VAF 14/57 reads (25%) | catalogued as rs929587245, COSV99961811, COSV99962155; called by muse, mutect2, varscan2
- TUBB7P | n.1245C>G | RNA (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
